CCDI case PBBXLT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/4502a30c-e66e-48d7-a70a-b950609c5c34

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Lymph nodes of multiple regions; Age at diagnosis: 17.2 years (6,298 days).

Biospecimens (3 samples)
- Sample 0DK0AF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK0AH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK0AO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
